Somatic mutation profile of tumor specimen MP2PRT-PARTAW-TMP1-A (aliquot MP2PRT-PARTAW-TMP1-A-1-0-D-A83C-36) from MP2PRT case MP2PRT-PARTAW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.7 years (2,441 days).
Specimen MP2PRT-PARTAW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dabc2034-6735-46ad-9cce-78c3f707916d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARTAW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARTAW-NB1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a359ee82-3988-4648-97a9-595ec52c8b26

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 14, Silent 3, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAZ1B | c.1265A>G p.K422R | Missense Mutation (SNP) | VAF 117/340 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs782674372; called by muse, mutect2, varscan2
- EZHIP | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 299/396 reads (76%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.748); catalogued as COSV57955761; called by muse, mutect2, varscan2
- GASK1A | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 189/513 reads (37%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs1238297647, COSV56186912; called by muse, mutect2, varscan2
- KIAA1614 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 177/486 reads (36%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs768311168; called by muse, mutect2, varscan2
- SHISA7 | c.1585C>T p.R529C | Missense Mutation (SNP) | VAF 174/484 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV66244761; called by muse, mutect2, varscan2
- BCORL1 | c.4990C>T p.Q1664* | Nonsense Mutation (SNP) | VAF 59/451 reads (13%) | called by muse, mutect2, varscan2
- ERVV-1 | c.853A>G p.T285A | Missense Mutation (SNP) | VAF 124/554 reads (22%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- FOXR2 | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 284/306 reads (93%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR39 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 209/498 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- IGHV1-69 | chr14:106714676 del ACTGTGTCT | Missense Mutation (DEL) | VAF 44/62 reads (71%) | called by mutect2, pindel, varscan2
- IGHV4-59 | c.349_350insGCCCC | In Frame Ins (INS) | VAF 18/43 reads (42%) | called by mutect2, pindel, varscan2
- IGKV1OR2-108 | chr2:113406870 ATTCACAGT>TCAGGGA | Missense Mutation (DEL) | VAF 26/54 reads (48%) | called by muse*, pindel
- IGKV2D-30 | chr2:89937672 ACTGGCCTCCCACAGTGGTACAGCCCTGA>CCCTGGGGGGGACCAAT | Missense Mutation (DEL) | VAF 6/50 reads (12%) | called by mutect2*, pindel, varscan2*
- MSLN | c.523T>G p.S175A | Missense Mutation (SNP) | VAF 34/552 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.403); called by muse, mutect2
- NAALAD2 | c.716C>G p.P239R | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF316 | c.2980G>A p.G994R | Missense Mutation (SNP) | VAF 303/651 reads (47%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2, varscan2
- NCKAP5 | c.5505C>T p.F1835= | Silent (SNP) | VAF 184/512 reads (36%) | catalogued as rs371665873; called by muse, mutect2, varscan2
- PTPRM | c.3444C>T p.H1148= | Silent (SNP) | VAF 84/244 reads (34%) | catalogued as rs748093155, COSV59841645; called by muse, mutect2, varscan2
- TENM2 | c.6276C>A p.T2092= (on ENST00000518659 / NM_001122679.2; = p.T1853= on NM_001080428.3) | Silent (SNP) | VAF 165/391 reads (42%) | called by muse, mutect2, varscan2
